Somatic mutation profile of tumor specimen MP2PRT-PAVUYL-TMP1-A (aliquot MP2PRT-PAVUYL-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVUYL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,013 days).
Specimen MP2PRT-PAVUYL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56ecb0c5-0501-455e-a01a-021d6f629d3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUYL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUYL-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf34b680-a3d0-4a03-b4af-018449d64bc1

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 36/442 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS14 | c.1686del p.S563Hfs*30 | Frame Shift Del (DEL) | VAF 260/817 reads (32%) | catalogued as rs1286385987, COSV64603559; called by mutect2, pindel, varscan2
- DCAF4L2 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 56/568 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1049152994, COSV100150671, COSV60476277, COSV60478817; called by muse, mutect2
- MAP2 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.099); catalogued as rs1166578294; called by muse, mutect2
- DOCK3 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 45/428 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRT6B | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2
- MIR9-1HG | n.517T>C | RNA (SNP) | VAF 70/192 reads (36%) | called by muse, mutect2, varscan2
